Somatic mutation profile of tumor specimen TCGA-W5-AA2J-01A (aliquot TCGA-W5-AA2J-01A-31D-A46P-09) from TCGA case TCGA-W5-AA2J, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.1 years (24,140 days).
Specimen TCGA-W5-AA2J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e058776e-c4b8-4f6b-8785-5924f1785499.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2J-10A (Blood Derived Normal), aliquot TCGA-W5-AA2J-10A-01D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d16f2138-9e3e-476e-88d6-6bcbaec87038

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA2D1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1338611631, COSV100666536, COSV100666987; called by muse, mutect2, varscan2
- CTNNA2 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV58154482; called by muse, mutect2
- GUCY1B1 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as rs371047617; called by muse, mutect2, varscan2
- LRP1B | c.12611A>G p.N4204S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV101251572, COSV67238657; called by muse, mutect2
- LRRC56 | c.837G>T p.E279D | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.045); catalogued as COSV99530632; called by muse, mutect2, varscan2
- MCUB | c.743T>C p.M248T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142171148; called by mutect2, varscan2
- PBRM1 | c.2237A>G p.Y746C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56288592; called by mutect2, varscan2
- SYDE1 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV54621493, COSV54623607; called by muse, mutect2
- TUBA3C | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as rs751625390, COSV67138830; called by muse, mutect2, varscan2
- ZIC4 | c.26T>C p.M9T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs771870317; called by mutect2, varscan2
- ADAMTSL1 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.058); called by muse, mutect2
- COL22A1 | c.3313_3317dup p.I1106Mfs*3 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | called by mutect2, pindel
- CPSF6 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CUL9 | c.4624G>T p.A1542S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); called by muse, mutect2
- EYA4 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.031); called by muse, mutect2
- KCNT2 | c.2550C>G p.F850L | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PCLO | c.13757dup p.R4587Kfs*11 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- PTPRD | c.1415C>A p.A472D | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TMEM150A | c.595G>A p.E199K (on ENST00000334462 / NM_001031738.3; = p.E146K on NM_153342.3) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- XIRP2 | c.2396G>T p.G799V (on ENST00000628543; = p.G974V on NM_152381.6) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF550 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.1449G>T p.R483= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- ARHGAP5 | c.2562T>G p.V854= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- C5 | c.3636G>A p.L1212= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, varscan2
- DOCK8 | c.5406C>T p.S1802= | Silent (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- PCDHA4 | c.2046G>A p.A682= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV63540205; called by muse, mutect2
- TAS2R7 | c.411C>T p.C137= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs375435543; called by muse, mutect2, varscan2
